Gene-level copy-number profile of tumor specimen TCGA-KL-8338-01A from TCGA case TCGA-KL-8338, project TCGA-KICH (Kidney Chromophobe). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, chromophobe type; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 51.1 years (18,667 days).
Specimen TCGA-KL-8338-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KICH.135b8050-e077-430b-aa42-ed973623568a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-KL-8338-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; AscatNGS; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f869b045-76b9-4625-a6e7-b6ce9aa26f8d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 21,900; copy number 2: 37,920.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-KL-8338-01A-11D-2308-01): tumor purity 0.82, ploidy 1.65, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 19,513. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
